Somatic mutation profile of tumor specimen TCGA-CN-6996-01A (aliquot TCGA-CN-6996-01A-11D-1912-08) from TCGA case TCGA-CN-6996, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,447 days).
Specimen TCGA-CN-6996-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd232f8d-2d5d-463c-a951-f7a2ba5b7347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6996-10A (Blood Derived Normal), aliquot TCGA-CN-6996-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65bcb1cd-7b78-4113-9e17-1c67b0f4b44f

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863223426, CM106873, COSV101001618; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.3695G>A p.G1232D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1292336494, COSV99899669; called by muse, mutect2, varscan2
- CD2AP | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100830609; called by muse, mutect2, varscan2
- CLN6 | c.515A>T p.Y172F | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV99992694; called by muse, mutect2, varscan2
- DDIAS | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.808); catalogued as COSV100231402; called by muse, mutect2
- DRAXIN | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV53844005, COSV99610914; called by muse, mutect2, varscan2
- EGF | c.866T>A p.F289Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.424); catalogued as COSV99491295; called by muse, mutect2, varscan2
- EPHA4 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs927390651, COSV99917315; called by muse, mutect2, varscan2
- FNDC4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV99254025; called by muse, mutect2, varscan2
- FUBP1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99629169, COSV99629462; called by muse, mutect2, varscan2
- FXR1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV99976622; called by muse, mutect2, varscan2
- GALNT5 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV99375509; called by muse, mutect2, varscan2
- HGD | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52198245; called by muse, mutect2, varscan2
- HSD17B4 | c.2097A>C p.K699N (on ENST00000414835 / NM_001199291.3; = p.K674N on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV99820094; called by muse, mutect2, varscan2
- KDR | c.2475C>A p.S825R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99818461; called by muse, mutect2, varscan2
- KMT2D | c.6777G>C p.E2259D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV99985174; called by muse, mutect2
- LIMK1 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100283411; called by muse, mutect2, varscan2
- LIN54 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100464928; called by muse, mutect2
- LMO7 | c.4222T>C p.S1408P (on ENST00000357063; = p.S1089P on NM_005358.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413798; called by muse, mutect2, varscan2
- LRRC37A2 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV100238824; called by mutect2, varscan2
- NHS | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs758435083, COSV66271082; called by muse, mutect2, varscan2
- PDHA1 | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV100135468; called by muse, mutect2
- RGMB | c.281G>A p.R94Q (on ENST00000513185 / NM_001366508.1; = p.R135Q on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768159076, COSV100375007; called by muse, mutect2, varscan2
- RTKN | c.1552A>G p.T518A (on ENST00000272430 / NM_001015055.2; = p.T505A on NM_033046.2) | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV99269882; called by muse, mutect2, varscan2
- RTKN | c.1221G>A p.W407* (on ENST00000272430 / NM_001015055.2; = p.W394* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 65/278 reads (23%) | catalogued as COSV99269400; called by muse, mutect2, varscan2
- SCN3A | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.568); catalogued as rs1414797037, COSV99328186; called by muse, mutect2, varscan2
- SEMA7A | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984967; called by muse, mutect2, varscan2
- SETX | c.3835G>C p.E1279Q | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV99810683; called by muse, mutect2, varscan2
- SH2D3C | c.1334G>A p.R445H (on ENST00000314830 / NM_170600.3; = p.R288H on NM_005489.4) | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); catalogued as rs776057887, COSV100137345; called by muse, mutect2, varscan2
- SLC7A7 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99591283; called by muse, mutect2, varscan2
- SUPV3L1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV100669855; called by muse, mutect2, varscan2
- ZBTB33 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100434301; called by muse, mutect2, varscan2
- ZGRF1 | c.2604G>C p.V868= | Splice Region (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100005725; called by muse, mutect2
- ZNF157 | c.1468A>G p.R490G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100998524; called by muse, mutect2, varscan2
- ZNF300 | c.1372G>T p.V458F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99200030; called by muse, mutect2, varscan2
- ZNF671 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV100235225; called by muse, mutect2, varscan2
- CEP85L | c.663del p.K221Nfs*32 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- NKTR | c.2589_2590del p.N864Sfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- A1CF | c.894C>T p.V298= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99257408; called by muse, mutect2, varscan2
- ACAD10 | c.777G>A p.V259= | Silent (SNP) | VAF 27/239 reads (11%) | catalogued as COSV58155588; called by muse, mutect2, varscan2
- AHNAK | c.8739A>G p.E2913= | Silent (SNP) | VAF 86/415 reads (21%) | catalogued as COSV99949128; called by muse, mutect2, varscan2
- ARMH4 | c.202C>T p.L68= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as COSV99958852; called by muse, mutect2, varscan2
- GTSE1 | c.2019C>T p.C673= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as rs61737807; called by muse, mutect2, varscan2
- KCNF1 | c.1275C>T p.H425= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs768454594, COSV54464004; called by muse, mutect2, varscan2
- PCED1A | c.990G>A p.Q330= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100642933; called by muse, mutect2
- PIK3CB | c.2583T>G p.A861= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100005997; called by muse, mutect2, varscan2
- PTGS2 | c.135C>T p.T45= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100821835, COSV66568378; called by muse, mutect2, varscan2
- RBM34 | c.177C>G p.L59= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100784035; called by muse, mutect2, varscan2
- SNORD50B | chr6:85677353 A>C | 3'Flank (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
